Somatic mutation profile of tumor specimen TCGA-B5-A1MX-01A (aliquot TCGA-B5-A1MX-01A-11D-A142-09) from TCGA case TCGA-B5-A1MX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 47.4 years (17,320 days).
Specimen TCGA-B5-A1MX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c02d065f-3609-4ee1-abf3-587c550d3f81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A1MX-10A (Blood Derived Normal), aliquot TCGA-B5-A1MX-10A-01D-A142-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ede913b4-1265-447d-9521-54b989b7da96

The open-access MAF lists 7,219 somatic variants for this specimen: 5,201 protein-altering or splice-affecting, 1,836 silent, 182 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4,104, Silent 1,836, Nonsense Mutation 325, Frame Shift Del 319, Frame Shift Ins 188, Splice Site 186, Intron 76, Splice Region 61, RNA 41, 3'UTR 23, 5'Flank 17, 3'Flank 16.

Variants (750 of 7,219; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.4537del p.Q1513Rfs*13 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | catalogued as rs281865377, HD070028; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- AGXT | c.33dup p.K12Qfs*156 | Frame Shift Ins (INS) | VAF 34/82 reads (41%) | catalogued as rs180177201; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AKT1 | c.155T>A p.L52H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62572203, COSV62573812; called by muse, mutect2, varscan2
- ATP2A1 | c.2464dup p.R822Pfs*39 | Frame Shift Ins (INS) | VAF 24/67 reads (36%) | catalogued as rs751365374; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BSCL2 | c.782dup p.I262Hfs*12 | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | catalogued as rs749890533; ClinVar: pathogenic; called by mutect2, varscan2
- COL11A2 | c.966dup p.T323Hfs*19 | Frame Shift Ins (INS) | VAF 12/20 reads (60%) | catalogued as rs748440351; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- DLD | c.633dup p.V212Sfs*32 | Frame Shift Ins (INS) | VAF 24/57 reads (42%) | catalogued as rs1040811473; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- DNAAF3 | c.997dup p.D333Gfs*64 (on ENST00000524407 / NM_001256715.2; = p.D380Gfs*64 on NM_178837.4) | Frame Shift Ins (INS) | VAF 18/40 reads (45%) | catalogued as rs756430359; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- EIF2AK3 | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs121908569, CM001982, CM141520, COSV57547925, COSV57548278; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBP1 | c.704dup p.D236Rfs*2 | Frame Shift Ins (INS) | VAF 14/51 reads (27%) | catalogued as rs774362519; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FKRP | c.1141dup p.A381Gfs*9 | Frame Shift Ins (INS) | VAF 17/66 reads (26%) | catalogued as rs754403441; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- GLA | c.708G>T p.W236C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869312386, CM960769, COSV54509978; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POLD1 | c.1433G>A p.S478N | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs397514632, CM1212503, COSV70955559; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.254-1G>A p.X85_splice | Splice Site (SNP) | VAF 9/25 reads (36%) | hotspot (GDC flag); catalogued as rs1057520208, COSV100910231, COSV64295507; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.493G>T p.G165* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | hotspot (GDC flag); catalogued as rs587782603, CM109590, CM110122, CM132268, COSV100910106, COSV64289126, COSV64290825; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 9/28 reads (32%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- SACS | c.3328del p.I1110Lfs*16 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs770866403; ClinVar: likely pathogenic; called by mutect2, varscan2
- SLC16A1 | c.41del p.P14Qfs*10 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, varscan2
- SPINK5 | c.2468del p.K823Rfs*101 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs565782662; ClinVar: pathogenic; called by mutect2, varscan2
- SUOX | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121908007, CM971431; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TMEM126B | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as rs886037857, COSV100729018; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMEM216 | c.228dup p.G77Wfs*16 (on ENST00000515837 / NM_001173990.3; = p.G16Wfs*16 on NM_016499.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 18/54 reads (33%) | catalogued as rs767384710; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ZC3H14 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as rs886037950, CM116199, COSV99193053; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AANAT | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99166216; called by muse, mutect2, varscan2
- AARS2 | c.1292T>C p.M431T | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99771442; called by muse, mutect2, varscan2
- AASDH | c.2423A>G p.Q808R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99221261; called by muse, mutect2, varscan2
- AASDH | c.1319del p.L440Wfs*43 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs770970036; called by mutect2, varscan2
- ABAT | c.317-1G>T p.X106_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99190944; called by muse, mutect2, varscan2
- ABCA12 | c.6809T>C p.I2270T (on ENST00000272895 / NM_173076.3; = p.I1952T on NM_015657.3) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as COSV99789884; called by muse, mutect2, varscan2
- ABCA13 | c.4388T>C p.L1463S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101330036; called by muse, mutect2, varscan2
- ABCA13 | c.7037T>C p.L2346S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.093); catalogued as COSV101446953; called by muse, mutect2, varscan2
- ABCA13 | c.10711T>C p.F3571L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101446954, COSV101447046; called by muse, mutect2, varscan2
- ABCA13 | c.14669G>A p.C4890Y | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV101291337; called by muse, mutect2, varscan2
- ABCA3 | c.4025G>T p.R1342M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV100068457; called by muse, mutect2, varscan2
- ABCA3 | c.3005-1G>T p.X1002_splice | Splice Site (SNP) | VAF 7/15 reads (47%) | catalogued as CS066265, COSV100068458; called by muse, varscan2
- ABCA3 | c.1797G>T p.Q599H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV100068463; called by muse, mutect2, varscan2
- ABCA4 | c.6359G>A p.G2120E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV64676165; called by muse, mutect2, varscan2
- ABCA5 | c.3224C>A p.P1075H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101201135; called by muse, mutect2, varscan2
- ABCA8 | c.3310-1G>T p.X1104_splice | Splice Site (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99285729; called by muse, mutect2
- ABCA9 | c.4084G>T p.G1362C | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100383104; called by muse, mutect2, varscan2
- ABCA9 | c.2377G>T p.G793* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100383106, COSV60626474; called by muse, mutect2
- ABCA9 | c.1445G>T p.R482I | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100383107; called by muse, mutect2, varscan2
- ABCB10 | c.1444A>G p.I482V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV100747948; called by muse, mutect2, varscan2
- ABCB10 | c.1205C>T p.T402I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV100747952; called by muse, mutect2, varscan2
- ABCC1 | c.3507G>T p.E1169D | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.35); catalogued as COSV100579530; called by muse, mutect2, varscan2
- ABCC10 | c.289C>T p.P97S (on ENST00000372530 / NM_001198934.2; = p.P54S on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV99767245; called by muse, mutect2, varscan2
- ABCC12 | c.1295C>A p.T432N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100252682; called by muse, mutect2, varscan2
- ABCC3 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.511); catalogued as COSV99559135; called by muse, mutect2, varscan2
- ABCC5 | c.1466A>G p.K489R | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV99656890; called by muse, mutect2
- ABCC6 | c.2888G>A p.C963Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.446); catalogued as COSV99228748; called by muse, mutect2, varscan2
- ABCC6 | c.2626G>T p.G876C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as COSV99228750; called by muse, mutect2, varscan2
- ABCC6 | c.998G>A p.S333N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as COSV52748155; called by muse, varscan2
- ABCC8 | c.4622C>T p.T1541I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100217247; called by muse, mutect2, varscan2
- ABCC9 | c.1238T>A p.I413N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV99685679; called by muse, mutect2, varscan2
- ABCF1 | c.419G>T p.S140I | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV100400836, COSV58228732; called by muse, mutect2, varscan2
- ABCG1 | c.1010A>T p.N337I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV100494179; called by muse, mutect2, varscan2
- ABCG4 | c.1181T>C p.L394P | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100266760; called by muse, mutect2
- ABCG5 | c.990G>T p.K330N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as rs1339151172, COSV99575211; called by muse, mutect2, varscan2
- ABCG5 | c.743C>T p.T248I | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99575381; called by muse, mutect2, varscan2
- ABHD12 | c.1037G>A p.S346N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99405078; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1211C>T p.T404I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68344085; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1431G>T p.E477D | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.461); catalogued as COSV101352255; called by muse, mutect2, varscan2
- ABHD3 | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); catalogued as COSV100004365; called by muse, mutect2, varscan2
- ABI1 | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV100697878; called by muse, mutect2, varscan2
- ABI3BP | c.2935A>G p.R979G | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99426746; called by muse, mutect2, varscan2
- ABR | c.2159C>T p.T720M (on ENST00000302538 / NM_021962.5; = p.T683M on NM_001092.5) | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs1304384646, COSV99347938; called by muse, mutect2, varscan2
- ABR | c.231G>T p.E77D | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.03); catalogued as COSV100215268; called by muse, mutect2, varscan2
- AC008397.2 | c.1503G>A p.M501I | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs748536731, COSV99441684; called by muse, mutect2, varscan2
- AC011462.1 | c.1265G>T p.R422M | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV99524573; called by muse, mutect2, varscan2
- AC068580.4 | c.207G>T p.E69D | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99362384; called by muse, mutect2, varscan2
- AC068580.4 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99362385; called by muse, mutect2, varscan2
- AC090517.4 | c.1303C>A p.L435I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99974465; called by muse, mutect2, varscan2
- AC109583.1 | c.309C>A p.S103= | Splice Region (SNP) | VAF 23/64 reads (36%) | catalogued as COSV100167889; called by muse, mutect2, varscan2
- AC144573.1 | c.735G>T p.K245N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100294489; called by muse, varscan2
- AC244197.3 | c.869T>C p.V290A | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV100557995; called by muse, mutect2, varscan2
- ACACB | c.6590C>T p.A2197V | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs143111072; called by muse, mutect2, varscan2
- ACAD10 | c.2141G>T p.W714L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100564161; called by muse, mutect2, varscan2
- ACADL | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99284744; called by muse, varscan2
- ACADL | c.619G>T p.G207W | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99284746; called by muse, varscan2
- ACADVL | c.201G>T p.K67N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99138508; called by mutect2, varscan2
- ACAN | c.722C>T p.T241I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757798845, COSV100718072; called by muse, mutect2, varscan2
- ACAP3 | c.816G>T p.E272D | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100686451; called by muse, mutect2
- ACHE | c.1785G>T p.M595I | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99574078; called by muse, mutect2, varscan2
- ACHE | c.1438T>C p.Y480H | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99574081; called by muse, mutect2, varscan2
- ACHE | c.1337C>A p.A446D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99574083; called by muse, mutect2, varscan2
- ACKR1 | c.185T>C p.L62P | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV100929559; called by muse, mutect2, varscan2
- ACMSD | c.670C>T p.H224Y | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99299051; called by muse, mutect2, varscan2
- ACMSD | c.949-1G>T p.X317_splice | Splice Site (SNP) | VAF 8/16 reads (50%) | catalogued as COSV99299053; called by muse, mutect2, varscan2
- ACO2 | c.956C>A p.A319D | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV99347379; called by muse, mutect2, varscan2
- ACOT1 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV100233418; called by muse, mutect2, varscan2
- ACOT9 | c.503G>A p.S168N | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100321274; called by muse, mutect2, varscan2
- ACOX2 | c.704-1G>T p.X235_splice | Splice Site (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100250160; called by muse, mutect2, varscan2
- ACR | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs1250026275, COSV99334429; called by muse, mutect2, varscan2
- ACSBG1 | c.1975C>A p.Q659K | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99357386; called by muse, mutect2, varscan2
- ACSL1 | c.85A>G p.T29A | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV99860631; called by muse, mutect2, varscan2
- ACSM2A | c.1457_1458insA p.A487Cfs*4 (on ENST00000219054; = p.A408Cfs*4 on NM_001308169.2) | Frame Shift Ins (INS) | VAF 13/92 reads (14%) | catalogued as COSV99525228; called by mutect2, pindel, varscan2
- ACSM3 | c.627G>T p.K209N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV99184494, COSV99184804; called by muse, varscan2
- ACSM5 | c.1112G>A p.G371D | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100088905; called by muse, mutect2
- ACSS1 | c.745C>A p.L249M | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV100053730; called by muse, mutect2, varscan2
- ACSS3 | c.651G>T p.K217N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV54092896, COSV99698260; called by muse, mutect2, varscan2
- ACTL7B | c.886T>C p.F296L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV101012523; called by muse, mutect2
- ACTN4 | c.1220G>T p.R407M | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99400201; called by muse, mutect2, varscan2
- ACTR10 | c.1071A>G p.G357= | Splice Region (SNP) | VAF 5/12 reads (42%) | catalogued as COSV99581141; called by muse, mutect2, varscan2
- ACTR2 | c.338C>A p.P113H | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99573896; called by muse, mutect2, varscan2
- ACTRT2 | c.347C>A p.P116H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101007605, COSV65760697; called by muse, mutect2, varscan2
- ACVR1C | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV99694676, COSV99695265; called by muse, mutect2, varscan2
- ADAM18 | c.203A>G p.Q68R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV99695535; called by mutect2, varscan2
- ADAM22 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.268); catalogued as COSV55974173, COSV99716897; called by muse, mutect2, varscan2
- ADAM28 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV99738651; called by muse, mutect2, varscan2
- ADAMTS12 | c.3374G>T p.S1125I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV100710918; called by muse, mutect2, varscan2
- ADAMTS12 | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100710919; called by muse, mutect2, varscan2
- ADAMTS13 | c.1747G>A p.V583I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV100747076; called by muse, mutect2, varscan2
- ADAMTS13 | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as rs782470631, COSV100747077; called by muse, mutect2, varscan2
- ADAMTS13 | c.2862G>A p.R954= | Splice Region (SNP) | VAF 20/72 reads (28%) | catalogued as COSV100747078; called by muse, mutect2, varscan2
- ADAMTS14 | c.1849C>T p.Q617* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100941578; called by muse, mutect2, varscan2
- ADAMTS16 | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.549); catalogued as rs777481925, COSV99941139, COSV99943598; called by muse, mutect2, varscan2
- ADAMTS16 | c.1163G>A p.G388D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99941140; called by muse, mutect2, varscan2
- ADAMTS17 | c.1412G>A p.S471N | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as rs367991535; called by muse, mutect2, varscan2
- ADAMTS17 | c.641G>T p.R214M | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV99170665; called by muse, mutect2, varscan2
- ADAMTS18 | c.2659G>A p.V887I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs370157524; called by muse, mutect2, varscan2
- ADAMTS7 | c.533C>A p.A178D | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101183101; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1501G>A p.V501I | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV99442687; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1439A>G p.D480G | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV99647297; called by muse, mutect2, varscan2
- ADAR | c.2827G>A p.A943T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99425978; called by muse, mutect2, varscan2
- ADAR | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as rs139492641; called by muse, mutect2, varscan2
- ADARB1 | c.1685G>A p.R562H (on ENST00000360697 / NM_001346687.2; = p.R522H on NM_001112.4) | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100653815; called by muse, mutect2
- ADCY10 | c.4790dup p.N1597Kfs*8 | Frame Shift Ins (INS) | VAF 24/67 reads (36%) | catalogued as rs753500756; called by mutect2, varscan2
- ADCY6 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs1481467261, COSV100326624; called by muse, mutect2, varscan2
- ADCY8 | c.2746G>T p.G916* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99652256; called by muse, mutect2, varscan2
- ADD1 | c.1279T>C p.S427P | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99296449; called by muse, mutect2, varscan2
- ADD3 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99523404; called by muse, mutect2, varscan2
- ADGRA3 | c.3427A>T p.T1143S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.754); catalogued as rs143592195, COSV99292772; called by muse, mutect2, varscan2
- ADGRB2 | c.2864C>T p.A955V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0.326); catalogued as rs867404976, COSV99926209; called by muse, mutect2, varscan2
- ADGRD1 | c.2614T>A p.S872T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99895403; called by muse, mutect2, varscan2
- ADGRE2 | c.667T>C p.C223R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV100216010; called by muse, mutect2, varscan2
- ADGRE5 | c.898-1G>T p.X300_splice (on ENST00000242786 / NM_078481.4; = p.X207_splice on NM_001784.5) | Splice Site (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99662904; called by muse, mutect2
- ADGRF2 | c.397T>G p.F133V (on ENST00000296862 / NM_001368115.2; = p.F65V on NM_153839.7) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99731193; called by muse, mutect2, varscan2
- ADGRG5 | c.608dup p.W204Lfs*4 | Frame Shift Ins (INS) | VAF 7/24 reads (29%) | catalogued as rs750862917; called by mutect2, varscan2
- ADGRG7 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs756988832, COSV56295668; called by muse, varscan2
- ADGRL2 | c.4G>A p.V2M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99588999; called by muse, varscan2
- ADGRL2 | c.1837G>A p.V613M (on ENST00000370717 / NM_001366005.1; = p.V600M on NM_012302.4) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99589002; called by muse, mutect2, varscan2
- ADGRL3 | c.1684C>A p.L562I (on ENST00000506720 / NM_001322402.2; = p.L494I on NM_015236.6) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV101547109; called by muse, mutect2, varscan2
- ADGRL3 | c.1771G>A p.A591T (on ENST00000506720 / NM_001322402.2; = p.A523T on NM_015236.6) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV101547110; called by muse, mutect2, varscan2
- ADGRV1 | c.4350G>T p.K1450N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV101315932; called by muse, varscan2
- ADGRV1 | c.6868G>T p.G2290C | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101315933, COSV67982944; called by muse, mutect2, varscan2
- ADGRV1 | c.18638G>T p.W6213L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101315934; called by muse, mutect2
- ADH1A | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV52925726; called by muse, mutect2, varscan2
- ADNP | c.2594A>G p.K865R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.956); catalogued as COSV100823746; called by muse, mutect2, varscan2
- ADORA2A | c.991G>T p.G331* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100418016; called by muse, mutect2, varscan2
- ADRA1A | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99370928; called by muse, mutect2, varscan2
- ADSL | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV99342230; called by muse, mutect2, varscan2
- AEBP1 | c.869C>A p.P290H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV99788766; called by muse, mutect2, varscan2
- AEBP1 | c.1805T>C p.M602T | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99788767; called by muse, mutect2, varscan2
- AEBP1 | c.2810-1G>A p.X937_splice | Splice Site (SNP) | VAF 5/17 reads (29%) | catalogued as COSV99788769; called by muse, mutect2, varscan2
- AF196969.1 | c.405G>A p.W135* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV99339339; called by muse, mutect2, varscan2
- AFAP1L1 | c.1704G>T p.E568D | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV99695894; called by muse, mutect2, varscan2
- AFF1 | c.452G>A p.C151Y | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV100320571; called by muse, mutect2, varscan2
- AFF3 | c.3373T>C p.S1125P | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100418829; called by muse, varscan2
- AFF3 | c.3238del p.R1080Gfs*5 | Frame Shift Del (DEL) | VAF 19/53 reads (36%) | catalogued as COSV57872946; called by mutect2, pindel, varscan2
- AFF3 | c.2082G>T p.Q694H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100418831; called by muse, mutect2
- AFG3L2 | c.836G>A p.G279D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99301879; called by muse, varscan2
- AFTPH | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV99480720; called by muse, mutect2, varscan2
- AGAP2 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs1166520661, COSV99223147; called by muse, mutect2, varscan2
- AGAP6 | c.1918T>C p.Y640H (on ENST00000374056 / NM_001365867.1; = p.Y663H on NM_001077665.2) | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100929088; called by muse, mutect2, varscan2
- AGBL4 | c.560A>G p.D187G | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.158); catalogued as COSV100886850; called by muse, mutect2, varscan2
- AGER | c.1185G>T p.E395D | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV100426185; called by muse, mutect2, varscan2
- AGK | c.407T>C p.L136P | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100814620; called by muse, mutect2, varscan2
- AGK | c.632G>T p.W211L | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.12); PolyPhen benign (0.327); catalogued as COSV100814621; called by muse, mutect2, varscan2
- AGK | c.873G>T p.Q291H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100814607, COSV100814622; called by muse, mutect2
- AGK | c.1214A>G p.Q405R | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100814623; called by muse, mutect2, varscan2
- AGL | c.1253C>A p.P418H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); catalogued as COSV99649196; called by muse, mutect2
- AGL | c.2812G>T p.G938C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs922506679, COSV99649197; called by muse, mutect2, varscan2
- AGO4 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100942935; called by muse, mutect2, varscan2
- AGPAT1 | c.678G>A p.S226= | Splice Region (SNP) | VAF 13/23 reads (57%) | catalogued as rs747761876, COSV100421630; called by muse, mutect2, varscan2
- AGR3 | c.332C>A p.P111H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100123961; called by muse, mutect2, varscan2
- AGRN | c.3103G>A p.V1035M | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs756015484, COSV65069371; called by muse, mutect2, varscan2
- AGXT2 | c.59G>T p.R20M | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as COSV99183752; called by muse, mutect2, varscan2
- AHDC1 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.558); catalogued as COSV99899283; called by muse, mutect2, varscan2
- AHI1 | c.371A>G p.K124R | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.449); catalogued as COSV99662718; called by muse, mutect2, varscan2
- AHNAK | c.4712G>T p.S1571I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV99947405; called by muse, mutect2, varscan2
- AHNAK | c.2608G>T p.G870C | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99947408; called by muse, mutect2, varscan2
- AHNAK2 | c.16847C>T p.P5616L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as rs1269659603, COSV100317479; called by muse, mutect2, varscan2
- AHNAK2 | c.5328G>T p.E1776D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.978); catalogued as rs759751752; called by mutect2, varscan2
- AHRR | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs1226713109, COSV57096292; called by muse, mutect2, varscan2
- AIMP2 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99551878; called by muse, varscan2
- AIP | c.138G>T p.E46D | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV99653668; called by muse, mutect2, varscan2
- AIP | c.336G>T p.K112N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV99653671; called by muse, mutect2, varscan2
- AK7 | c.1132G>A p.V378M | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1252115766, COSV99967257, COSV99967530; called by muse, mutect2, varscan2
- AKAP1 | c.2574G>A p.Q858= | Splice Region (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100532873; called by muse, mutect2, varscan2
- AKAP12 | c.1433A>G p.Q478R | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV99483176; called by muse, mutect2, varscan2
- AKAP13 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63472095; called by muse, mutect2, varscan2
- AKAP17A | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs1315200319, COSV100002222; called by muse, mutect2, varscan2
- AKAP17A | c.248T>C p.V83A | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.992); catalogued as COSV100002223; called by muse, mutect2, varscan2
- AKAP17A | c.1230G>T p.Q410H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100002226; called by muse, mutect2, varscan2
- AKAP4 | c.277-3del | Splice Region (DEL) | VAF 4/10 reads (40%) | catalogued as rs1321821014; called by mutect2, varscan2
- AKAP4 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 26/64 reads (41%) | catalogued as COSV100654260, COSV62073534; called by muse, mutect2, varscan2
- AKAP5 | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV100277970; called by muse, mutect2, varscan2
- AKAP7 | c.428+1G>A p.X143_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | catalogued as rs761021276, COSV100818779; called by muse, mutect2, varscan2
- AKAP9 | c.5761G>A p.A1921T (on ENST00000359028; = p.A1889T on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.289); catalogued as rs182445675, COSV100662379; called by muse, mutect2, varscan2
- AKR1B15 | c.1017del p.F340Sfs*22 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | catalogued as COSV71152918; called by mutect2, varscan2
- AKR1C4 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV99578694; called by muse, varscan2
- AKTIP | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as COSV100289787; called by muse, mutect2, varscan2
- AL121899.2 | c.2013G>T p.K671N | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV101198448, COSV67349694; called by muse, mutect2, varscan2
- AL592490.1 | c.1162G>T p.G388* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV101308193; called by muse, mutect2, varscan2
- AL645922.1 | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100191089; called by muse, mutect2, varscan2
- ALAS2 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100238276; called by muse, mutect2, varscan2
- ALCAM | c.1191G>T p.Q397H | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.972); catalogued as COSV100064782; called by muse, mutect2, varscan2
- ALDH16A1 | c.358T>C p.W120R | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as rs775257484, COSV99512876; called by muse, mutect2, varscan2
- ALDH1A1 | c.64A>G p.K22E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV99921360; called by muse, mutect2, varscan2
- ALDH1L1 | c.2077C>T p.Q693* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV56421546, COSV99856821; called by muse, mutect2
- ALDH3B2 | c.512G>A p.C171Y | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100824035; called by muse, mutect2
- ALDH5A1 | c.1265C>A p.P422H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100708802; called by muse, mutect2, varscan2
- ALG10B | c.898T>C p.F300L | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs1177149052, COSV100439897; called by muse, varscan2
- ALG12 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | PolyPhen benign (0.026); catalogued as rs368695462, COSV100427099; called by muse, varscan2
- ALG14 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100930859; called by muse, mutect2, varscan2
- ALG8 | c.1300A>G p.M434V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as COSV100220078; called by muse, mutect2
- ALKBH5 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99232744; called by muse, mutect2, varscan2
- ALMS1 | c.5449C>T p.Q1817* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100042448; called by mutect2, varscan2
- ALMS1 | c.7828T>A p.S2610T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV100042450; called by mutect2, varscan2
- ALOX15B | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101205617; called by muse, mutect2, varscan2
- ALOX5 | c.1889C>A p.P630H | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100980064; called by muse, mutect2, varscan2
- ALOXE3 | c.2105C>A p.P702H | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59078365; called by muse, mutect2, varscan2
- ALPK1 | c.865A>C p.S289R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV99454074; called by muse, mutect2, varscan2
- ALPK3 | c.1992G>T p.Q664H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.557); catalogued as COSV99360898; called by mutect2, varscan2
- ALS2CL | c.2606C>T p.S869L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as rs766145175, COSV59673915; called by muse, mutect2, varscan2
- ALS2CL | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100015034; called by muse, mutect2, varscan2
- AMBRA1 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100093928; called by muse, mutect2, varscan2
- AMDHD1 | c.566G>A p.C189Y | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57137827; called by muse, mutect2, varscan2
- AMER1 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV57655000, COSV57655402; called by muse, mutect2, varscan2
- AMER2 | c.1246G>A p.V416M | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100766258; called by muse, varscan2
- AMFR | c.1599G>A p.Q533= | Splice Region (SNP) | VAF 16/31 reads (52%) | catalogued as COSV99315889; called by muse, mutect2, varscan2
- AMFR | c.667-1G>A p.X223_splice | Splice Site (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99315891; called by muse, mutect2
- AMIGO1 | c.1148G>T p.S383I | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100881059; called by muse, mutect2, varscan2
- AMIGO1 | c.293T>C p.L98P | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100881061; called by muse, mutect2, varscan2
- AMOTL2 | c.1119G>T p.E373D | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.991); catalogued as COSV99998167; called by muse, mutect2
- AMPD1 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs187527797; called by muse, mutect2, varscan2
- AMPD3 | c.1978C>A p.L660I (on ENST00000396553 / NM_001025389.2; = p.L669I on NM_000480.3) | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as COSV101158169; called by muse, mutect2
- AMPH | c.1609-1G>A p.X537_splice | Splice Site (SNP) | VAF 28/68 reads (41%) | catalogued as COSV100342060; called by muse, mutect2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 19/40 reads (48%) | catalogued as rs34047276; called by mutect2, varscan2
- ANGPTL6 | c.858G>A p.W286* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as COSV99463644; called by muse, mutect2, varscan2
- ANK1 | c.4369C>T p.R1457C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs778172143, COSV99225204; called by muse, mutect2, varscan2
- ANK1 | c.4028T>C p.L1343P | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV55881940, COSV99225206; called by muse, varscan2
- ANK2 | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100001599; called by muse, mutect2, varscan2
- ANK2 | c.8664G>T p.K2888N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.023); catalogued as COSV100001601; called by muse, mutect2, varscan2
- ANK3 | c.7588G>T p.V2530L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV99779910; called by muse, mutect2, varscan2
- ANK3 | c.4618A>T p.I1540L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.12); catalogued as COSV99779913; called by muse, mutect2, varscan2
- ANK3 | c.1192C>A p.L398M | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99779915; called by muse, mutect2, varscan2
- ANKAR | c.1804del p.R602Efs*29 | Frame Shift Del (DEL) | VAF 8/77 reads (10%) | catalogued as rs753688897; called by mutect2, pindel, varscan2
- ANKAR | c.1985G>A p.G662D | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV99854232; called by muse, mutect2, varscan2
- ANKH | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.137); catalogued as COSV99414985; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5045G>A p.R1682K | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.931); catalogued as COSV99783286; called by muse, mutect2, varscan2
- ANKLE1 | c.1610C>T p.A537V (on ENST00000394458; = p.A483V on NM_152363.6) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101082261; called by muse, mutect2, varscan2
- ANKLE2 | c.1843G>T p.E615* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as COSV100513913, COSV100514108; called by muse, mutect2, varscan2
- ANKMY2 | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1360021778, COSV100187084; called by muse, mutect2
- ANKRD11 | c.4930G>A p.G1644R | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.293); catalogued as rs1279832813, COSV99969271; called by muse, mutect2, varscan2
- ANKRD11 | c.87G>T p.K29N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV99969276; called by muse, mutect2, varscan2
- ANKRD13C | c.32G>T p.R11M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as COSV99256824; called by muse, mutect2
- ANKRD17 | c.4681A>G p.T1561A | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.13); catalogued as COSV100429192; called by muse, mutect2
- ANKRD17 | c.3034G>A p.V1012I | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV100429195; called by muse, mutect2, varscan2
- ANKRD20A2P | c.2468T>A p.I823N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.105); catalogued as COSV101111832; called by muse, mutect2, varscan2
- ANKRD26 | c.5121T>A p.N1707K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.048); catalogued as COSV101063201; called by muse, mutect2, varscan2
- ANKRD26 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV101063204; called by muse, mutect2, varscan2
- ANKRD27 | c.512T>C p.L171P | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100042801; called by muse, mutect2
- ANKRD27 | c.115T>C p.C39R | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.39); PolyPhen benign (0.222); catalogued as COSV100042802; called by muse, mutect2, varscan2
- ANKRD44 | c.821C>T p.T274I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99984971; called by muse, mutect2, varscan2
- ANKRD52 | c.1966del p.L656Cfs*16 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs1398063159; called by pindel, varscan2
- ANKRD53 | c.551G>T p.R184M | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV99721386; called by muse, mutect2, varscan2
- ANKRD55 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100591301; called by muse, mutect2, varscan2
- ANKRD9 | c.932T>C p.L311S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99743597; called by muse, mutect2, varscan2
- ANKS1A | c.1074G>T p.E358D | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.97); catalogued as COSV100832414; called by muse, mutect2, varscan2
- ANKS1A | c.1513G>A p.G505S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs773776936, COSV100832415; called by muse, mutect2, varscan2
- ANKZF1 | c.2161G>A p.A721T | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV99850522; called by muse, mutect2, varscan2
- ANO1 | c.2643G>T p.K881N | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV100797066; called by muse, mutect2, varscan2
- ANO4 | c.541G>A p.V181I (on ENST00000392977 / NM_001286615.2; = p.V146I on NM_178826.4) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1437771574, COSV100152862; called by muse, mutect2
- ANO4 | c.1774T>A p.F592I (on ENST00000392977 / NM_001286615.2; = p.F557I on NM_178826.4) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV100152863; called by muse, mutect2, varscan2
- ANO4 | c.2725C>A p.L909I (on ENST00000392977 / NM_001286615.2; = p.L874I on NM_178826.4) | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV100152864; called by muse, mutect2, varscan2
- ANO8 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.569); catalogued as COSV99344458; called by muse, mutect2
- ANP32B | c.55-1G>T p.X19_splice | Splice Site (SNP) | VAF 18/49 reads (37%) | catalogued as COSV100233245; called by muse, mutect2, varscan2
- ANP32E | c.792G>T p.E264D | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100029676; called by muse, mutect2, varscan2
- ANTXR1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.339); catalogued as COSV100362491; called by muse, mutect2, varscan2
- ANXA4 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV101268798; called by muse, mutect2, varscan2
- ANXA9 | c.506C>A p.S169Y | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs746463095, COSV100929097; called by muse, varscan2
- AOC1 | c.1121T>C p.V374A | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.244); catalogued as COSV100710775, COSV62866959; called by muse, mutect2, varscan2
- AOC1 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766467987, COSV100710776; called by muse, mutect2, varscan2
- AOC3 | c.971G>A p.S324N | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV99520145; called by muse, mutect2, varscan2
- AOX1 | c.1393G>T p.G465C | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV101021961; called by muse, mutect2, varscan2
- AOX1 | c.2295G>T p.E765D | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101021963; called by muse, mutect2, varscan2
- AP1B1 | c.2216C>T p.T739I | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.148); catalogued as rs1395587910, COSV100434586; called by muse, mutect2, varscan2
- AP1G1 | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV100250416; called by muse, mutect2, varscan2
- AP3B1 | c.843G>T p.K281N | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV99671342; called by mutect2, varscan2
- AP3D1 | c.2135C>A p.P712H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100642669; called by muse, mutect2, varscan2
- AP4M1 | c.351+1G>A p.X117_splice | Splice Site (SNP) | VAF 18/54 reads (33%) | catalogued as COSV100384894; called by muse, mutect2, varscan2
- APAF1 | c.2598G>A p.L866= (on ENST00000551964 / NM_181861.2; = p.L812= on NM_001160.3) | Splice Region (SNP) | VAF 35/77 reads (45%) | catalogued as COSV100244095; called by muse, mutect2, varscan2
- APBA3 | c.111G>A p.W37* | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | catalogued as COSV100349665; called by muse, mutect2, varscan2
- APBB1IP | c.1230G>T p.W410C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100882040; called by muse, mutect2, varscan2
- APC | c.2498G>T p.S833I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as CD106420, COSV99967778; called by muse, mutect2, varscan2
- API5 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as rs1161543377, COSV101124536; called by mutect2, varscan2
- APLNR | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs764929700, COSV99951442; called by muse, mutect2, varscan2
- APOBEC3D | c.666A>C p.K222N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.532); catalogued as COSV99328951; called by muse, mutect2, varscan2
- APOBEC3F | c.1066G>T p.G356* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100415195; called by muse, mutect2, varscan2
- APOBEC4 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100426124; called by muse, mutect2, varscan2
- APOBR | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100112554; called by muse, mutect2, varscan2
- APOBR | c.2518G>A p.A840T (on ENST00000431282; = p.A849T on NM_018690.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.625); catalogued as rs765777993, COSV100112556; called by muse, mutect2, varscan2
- APOL2 | c.137G>T p.R46M | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99969120; called by muse, mutect2
- APOOL | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs778748950, COSV100920835; called by muse, mutect2, varscan2
- AQP10 | c.856T>G p.S286A | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as COSV59246499; called by muse, mutect2, varscan2
- AQP5 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV99527477; called by muse, mutect2, varscan2
- AR | c.1769-1G>T p.X590_splice | Splice Site (SNP) | VAF 11/96 reads (11%) | catalogued as CS061248, COSV101018245; called by muse, mutect2, varscan2
- ARAF | c.909G>A p.W303* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as COSV51693112; called by muse, mutect2, varscan2
- ARAP3 | c.670G>T p.G224C | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.159); catalogued as COSV99499702; called by muse, mutect2, varscan2
- ARFGAP2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100096343; called by muse, mutect2, varscan2
- ARFGEF2 | c.1805G>T p.G602V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100904252; called by muse, mutect2, varscan2
- ARFGEF3 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99293450; called by muse, varscan2
- ARHGAP11A | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs186578850, COSV100853240; called by muse, mutect2, varscan2
- ARHGAP11B | c.640T>C p.S214P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV101451797; called by muse, mutect2, varscan2
- ARHGAP15 | c.481A>G p.T161A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs762738571, COSV99710599; called by muse, mutect2
- ARHGAP17 | c.2398G>A p.V800I (on ENST00000289968 / NM_001006634.3; = p.V722I on NM_018054.6) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV99253421; called by muse, mutect2, varscan2
- ARHGAP18 | c.1536G>A p.M512I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV100936167; called by muse, mutect2, varscan2
- ARHGAP19 | c.1149G>A p.M383I | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV100363162; called by muse, mutect2, varscan2
- ARHGAP19 | c.707C>A p.P236H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100363164; called by muse, mutect2, varscan2
- ARHGAP21 | c.5183C>T p.P1728L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV100256198; called by muse, mutect2, varscan2
- ARHGAP21 | c.4329G>T p.K1443N | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV100255754, COSV100256203; called by muse, mutect2, varscan2
- ARHGAP21 | c.2897G>T p.R966L | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57604973; called by muse, mutect2, varscan2
- ARHGAP24 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV101233070; called by muse, mutect2, varscan2
- ARHGAP25 | c.1116G>T p.K372N (on ENST00000409202 / NM_001007231.3; = p.K364N on NM_014882.3) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV54901425; called by muse, mutect2, varscan2
- ARHGAP26 | c.1211-1G>T p.X404_splice | Splice Site (SNP) | VAF 18/55 reads (33%) | catalogued as COSV99190927; called by muse, varscan2
- ARHGAP27 | c.1299G>T p.E433D (on ENST00000428638 / NM_001282290.1; = p.E92D on NM_199282.3) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100976514; called by muse, mutect2, varscan2
- ARHGAP29 | c.2965G>T p.G989C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99558154; called by muse, mutect2, varscan2
- ARHGAP29 | c.955-1G>A p.X319_splice | Splice Site (SNP) | VAF 6/29 reads (21%) | catalogued as rs867495465, COSV99558157; called by muse, mutect2, varscan2
- ARHGAP32 | c.4211C>T p.A1404V (on ENST00000310343 / NM_001378025.1; = p.A1055V on NM_014715.4) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); catalogued as rs552856918, COSV59848863; called by muse, mutect2, varscan2
- ARHGAP32 | c.1301C>T p.P434L (on ENST00000310343 / NM_001378025.1; = p.P85L on NM_014715.4) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.113); catalogued as rs1308028761, COSV100087846; called by muse, mutect2, varscan2
- ARHGAP36 | c.1377C>A p.I459= | Splice Region (SNP) | VAF 11/45 reads (24%) | catalogued as rs1436389659, COSV52272876, COSV99357677; called by muse, mutect2, varscan2
- ARHGAP45 | c.3345del p.M1116* | Frame Shift Del (DEL) | VAF 30/71 reads (42%) | catalogued as rs1384556233; called by mutect2, pindel, varscan2
- ARHGAP6 | c.2290C>A p.L764I (on ENST00000337414 / NM_013427.3; = p.L561I on NM_013423.3) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.366); catalogued as COSV100272821, COSV57292598; called by muse, varscan2
- ARHGEF10L | c.1271T>C p.I424T | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV99392838; called by muse, mutect2, varscan2
- ARHGEF10L | c.3612C>A p.S1204R | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.59); PolyPhen benign (0.062); catalogued as COSV99392845; called by muse, mutect2, varscan2
- ARHGEF12 | c.2015G>T p.G672V | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100754912; called by muse, mutect2, varscan2
- ARHGEF19 | c.821C>A p.P274H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99580416; called by muse, mutect2, varscan2
- ARHGEF4 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs200479089, COSV58117997; called by muse, mutect2, varscan2
- ARHGEF4 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100388092; called by muse, mutect2, varscan2
- ARHGEF5 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99282817; called by muse, mutect2, varscan2
- ARID1A | c.3629G>T p.G1210V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.794); catalogued as COSV100251664; called by muse, mutect2, varscan2
- ARID4A | c.2368C>T p.P790S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100794238; called by muse, mutect2, varscan2
- ARIH2 | c.1471C>T p.H491Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.84); PolyPhen benign (0.015); catalogued as COSV62704247; called by muse, mutect2, varscan2
- ARL13B | c.1084C>T p.L362F (on ENST00000394222 / NM_001174150.2; = p.L255F on NM_144996.4) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV100115061, COSV57402572; called by mutect2, varscan2
- ARL5A | c.121G>T p.V41F | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99706627; called by muse, mutect2, varscan2
- ARL9 | c.530A>G p.H177R (on ENST00000640821 / NM_001363794.2; = p.H35R on NM_206919.2) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.2); catalogued as COSV100781267; called by muse, mutect2, varscan2
- ARMC8 | c.1995G>T p.K665N (on ENST00000469044 / NM_001363941.2; = p.K651N on NM_015396.6) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100509609; called by muse, mutect2, varscan2
- ARMCX2 | c.904G>T p.V302F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as COSV100168150; called by muse, mutect2, varscan2
- ARMCX6 | c.88G>T p.G30* | Nonsense Mutation (SNP) | VAF 31/67 reads (46%) | catalogued as COSV100726223; called by muse, mutect2, varscan2
- ARMH3 | c.1984T>C p.S662P | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV99493372; called by muse, mutect2, varscan2
- ARSK | c.524G>T p.R175M | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.262); catalogued as COSV101187542; called by muse, mutect2, varscan2
- ARTN | c.74C>A p.P25H (on ENST00000372354; = p.P33H on NM_057090.2) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99495382; called by muse, mutect2
- ASAH2 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as rs771397769, COSV100269935; called by muse, mutect2, varscan2
- ASAP3 | c.538C>A p.Q180K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV100369438; called by muse, mutect2, varscan2
- ASB1 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.947); catalogued as COSV99223220; called by muse, mutect2, varscan2
- ASCC3 | c.6561G>T p.Q2187H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.371); catalogued as COSV100976193; called by muse, mutect2, varscan2
- ASH1L | c.3337G>T p.G1113W | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.704); catalogued as COSV100853411; called by muse, mutect2, varscan2
- ASH1L | c.383T>C p.M128T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as COSV100853412; called by muse, mutect2, varscan2
- ASH2L | c.1602G>T p.K534N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV99166972; called by muse, mutect2, varscan2
- ASIC3 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.341); catalogued as rs771099965, COSV99876932; called by muse, varscan2
- ASIC4 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.334); catalogued as rs762384202, COSV100761705; called by muse, mutect2, varscan2
- ASMTL | c.1645+1G>A p.X549_splice | Splice Site (SNP) | VAF 30/88 reads (34%) | catalogued as COSV101187755; called by muse, mutect2
- ASPA | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555538148, COSV99279247; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASPG | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.206); catalogued as COSV101496392; called by muse, mutect2, varscan2
- ASPM | c.7517C>A p.A2506D | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99660343; called by muse, mutect2, varscan2
- ASTN1 | c.3172C>A p.L1058I | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (1); PolyPhen probably damaging (0.979); catalogued as COSV100706686, COSV62497060; called by muse, mutect2, varscan2
- ASTN1 | c.284A>G p.E95G | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99921589; called by muse, mutect2, varscan2
- ASTN2 | c.2197A>G p.M733V (on ENST00000313400 / NM_001365069.1; = p.M682V on NM_014010.5) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs755501120, COSV100527367; called by mutect2, varscan2
- ASXL1 | c.793C>A p.R265S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100039171, COSV60103435; called by muse, mutect2, varscan2
- ASXL2 | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV99711088; called by muse, mutect2, varscan2
- ATAD3A | c.282+1G>A p.X94_splice | Splice Site (SNP) | VAF 5/51 reads (10%) | catalogued as COSV100186327; called by mutect2, varscan2
- ATAD3B | c.394C>A p.R132S (on ENST00000308647; = p.R238S on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs757344083, COSV100426461, COSV58020515; called by muse, mutect2, varscan2
- ATAT1 | c.752G>T p.W251L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.154); catalogued as COSV99527940; called by muse, mutect2, varscan2
- ATF4 | c.406dup p.Q136Pfs*44 | Frame Shift Ins (INS) | VAF 16/48 reads (33%) | catalogued as rs770192882; called by mutect2, varscan2
- ATF7 | c.698C>T p.A233V (on ENST00000548446 / NM_001366555.2; = p.A222V on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.074); catalogued as rs544146784, COSV100129441; called by mutect2, varscan2
- ATF7IP | c.407C>A p.P136H | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99661663; called by muse, mutect2, varscan2
- ATG14 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.172); catalogued as COSV99902794; called by muse, mutect2
- ATG7 | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV100607281; called by muse, varscan2
- ATL1 | c.195G>T p.K65N | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.737); catalogued as COSV100613115; called by muse, mutect2, varscan2
- ATM | c.3290T>C p.F1097S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99589595; called by muse, mutect2
- ATM | c.3993G>T p.Q1331H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV53731830, COSV53754803; called by muse, mutect2
- ATMIN | c.1478C>T p.T493I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100214622; called by muse, mutect2, varscan2
- ATP10B | c.2653G>T p.G885* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100514940; called by muse, mutect2, varscan2
- ATP10B | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as COSV100514941, COSV59150928; called by mutect2, varscan2
- ATP11B | c.386G>T p.S129I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV100017769; called by muse, mutect2, varscan2
- ATP11C | c.2691C>A p.F897L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100557896; called by muse, mutect2, varscan2
- ATP11C | c.1929G>A p.M643I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV59561895; called by muse, mutect2, varscan2
- ATP13A1 | c.1813G>T p.D605Y | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV99366133; called by muse, mutect2, varscan2
- ATP13A3 | c.1536del p.I513Ffs*22 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | catalogued as rs1560093924; called by mutect2, pindel, varscan2
- ATP1A2 | c.2564-1G>T p.X855_splice | Splice Site (SNP) | VAF 12/31 reads (39%) | catalogued as COSV100767827; called by muse, mutect2, varscan2
- ATP1A3 | c.739T>C p.F247L (on ENST00000545399 / NM_001256214.2; = p.F234L on NM_152296.5) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV100132247; called by muse, mutect2, varscan2
- ATP1A4 | c.1580C>T p.T527I | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100927544; called by muse, mutect2, varscan2
- ATP1B4 | c.650A>C p.K217T (on ENST00000218008 / NM_001142447.3; = p.K213T on NM_012069.5) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99486339; called by muse, mutect2, varscan2
- ATP2A2 | c.1337C>T p.T446I | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV100428601; called by muse, mutect2, varscan2
- ATP2B1 | c.2711C>T p.T904M | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99665677; called by muse, mutect2, varscan2
- ATP2B1 | c.929-2A>G p.X310_splice | Splice Site (SNP) | VAF 12/35 reads (34%) | catalogued as COSV99665681; called by muse, mutect2, varscan2
- ATP2B2 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59503462; called by muse, mutect2, varscan2
- ATP2B4 | c.2276C>T p.T759I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as COSV100397498; called by muse, mutect2, varscan2
- ATP4A | c.1365+1G>A p.X455_splice | Splice Site (SNP) | VAF 5/50 reads (10%) | catalogued as COSV99382575; called by muse, mutect2
- ATP5PD | c.35A>T p.D12V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100043149; called by muse, mutect2, varscan2
- ATP6AP2 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV101011492; called by muse, mutect2
- ATP6AP2 | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.098); catalogued as COSV101011493; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as rs1476032591, COSV99230944; called by muse, mutect2, varscan2
- ATP6V1C2 | c.778del p.E260Kfs*37 (on ENST00000272238 / NM_001039362.2; = p.E260Kfs*25 on NM_144583.4) | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | catalogued as COSV55360341; called by mutect2, pindel, varscan2
- ATP6V1D | c.302T>C p.V101A | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99370828; called by muse, mutect2, varscan2
- ATP7A | c.2491C>A p.L831I | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.108); catalogued as COSV58456820; called by muse, mutect2, varscan2
- ATP8A1 | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100046159, COSV52545556; called by muse, mutect2, varscan2
- ATP8B2 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV100270225; called by muse, mutect2, varscan2
- ATP8B4 | c.2443G>A p.D815N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99465440; called by muse, mutect2, varscan2
- ATP9B | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100303555; called by muse, mutect2, varscan2
- ATRN | c.3098C>T p.T1033I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.054); catalogued as rs373875730; called by muse, mutect2, varscan2
- ATRNL1 | c.3702del p.F1234Lfs*51 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as rs782019775, COSV58101402; called by pindel, varscan2
- ATXN7 | c.1933C>T p.Q645* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV99894403; called by muse, mutect2, varscan2
- ATXN7 | c.2193G>T p.M731I | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV99894405; called by muse, mutect2, varscan2
- ATXN7L2 | c.1656G>T p.K552N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100149835; called by muse, varscan2
- AUH | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100342428; called by muse, mutect2, varscan2
- AURKB | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as rs746973523, COSV100298725, COSV60246755; called by muse, mutect2, varscan2
- AUTS2 | c.2004G>T p.K668N | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100716850; called by muse, mutect2, varscan2
- AWAT1 | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100997200; called by muse, mutect2
- AWAT2 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as rs778820383, COSV99339656; called by muse, mutect2, varscan2
- B3GNTL1 | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.463); catalogued as COSV100301988; called by muse, mutect2, varscan2
- B4GALT2 | c.817A>G p.N273D | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100530774; called by muse, varscan2
- B4GAT1 | c.545G>A p.C182Y | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100240252; called by muse, mutect2
- BACH1 | c.1889T>C p.L630P | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV99728234; called by muse, mutect2, varscan2
- BAHCC1 | c.1922G>A p.S641N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100311632; called by muse, mutect2, varscan2
- BAIAP2 | c.1536-1G>T p.X512_splice | Splice Site (SNP) | VAF 15/25 reads (60%) | catalogued as COSV100352799; called by muse, mutect2, varscan2
- BAMBI | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV100977501; called by muse, mutect2, varscan2
- BANP | c.52C>A p.L18M | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99620815, COSV99621523; called by muse, mutect2, varscan2
- BAP1 | c.2175G>T p.K725N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99963945; called by muse, mutect2, varscan2
- BAZ1A | c.3272T>A p.I1091N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100701148; called by muse, mutect2, varscan2
- BAZ2A | c.4892C>T p.T1631I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99466146; called by muse, mutect2, varscan2
- BBS10 | c.1331G>T p.S444I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.406); catalogued as COSV101283392; called by muse, mutect2, varscan2
- BCAR1 | c.1491G>T p.Q497H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV99366629; called by muse, mutect2, varscan2
- BCAS1 | c.1675G>T p.G559C | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101006175; called by muse, mutect2, varscan2
- BCAS1 | c.1492G>T p.G498C | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV101006176; called by muse, mutect2, varscan2
- BCKDHB | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as rs1258111524, COSV100243593; called by muse, mutect2, varscan2
- BCL11B | c.770G>A p.S257N (on ENST00000357195 / NM_001282237.2; = p.S186N on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV100595520; called by muse, mutect2, varscan2
- BCL9L | c.634G>T p.G212C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100599838; called by muse, mutect2, varscan2
- BCLAF3 | c.1216C>A p.L406I | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.368); catalogued as rs1226007623, COSV100503296; called by muse, mutect2, varscan2
- BCOR | c.941G>T p.R314M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100653310; called by muse, mutect2, varscan2
- BCORL1 | c.132G>T p.Q44H | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99499409; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | catalogued as rs768244116; called by pindel, varscan2
- BCORL1 | c.5098C>A p.L1700I | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54407764, COSV99499411; called by muse, varscan2
- BCR | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100006504; called by muse, varscan2
- BDP1 | c.938dup p.L313Ffs*9 | Frame Shift Ins (INS) | VAF 10/20 reads (50%) | catalogued as rs752427670; called by mutect2, varscan2
- BDP1 | c.3645G>T p.E1215D | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.634); catalogued as COSV100703063; called by muse, mutect2, varscan2
- BDP1 | c.7637A>T p.N2546I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV100703067; called by muse, mutect2, varscan2
- BDP1 | c.7812G>T p.E2604D | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100703068; called by muse, mutect2, varscan2
- BECN1 | c.1208T>A p.I403N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100162102, COSV59312122; called by muse, mutect2, varscan2
- BEND6 | c.828G>T p.Q276H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100876843; called by mutect2, varscan2
- BFAR | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as COSV99902212; called by muse, mutect2, varscan2
- BICD1 | c.1909A>G p.K637E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99862403; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 14/25 reads (56%) | catalogued as rs755506199; called by mutect2, varscan2
- BICRA | c.2935del p.A979Pfs*67 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs756990560, COSV67605323; called by mutect2, pindel, varscan2
- BIRC6 | c.10424T>G p.M3475R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV101428279; called by muse, mutect2, varscan2
- BLK | c.369-1G>T p.X123_splice | Splice Site (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99377191; called by muse, mutect2, varscan2
- BLM | c.1959G>T p.K653N | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV100757210; called by muse, mutect2, varscan2
- BLMH | c.1331T>C p.L444P | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99913131; called by muse, mutect2, varscan2
- BLVRA | c.352G>T p.G118* | Nonsense Mutation (SNP) | VAF 15/27 reads (56%) | catalogued as COSV99645994; called by muse, mutect2, varscan2
- BMP3 | c.165G>T p.K55N | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as rs541377183, COSV99261671; called by muse, mutect2, varscan2
- BMPR1B | c.527T>C p.L176P | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771747962, COSV99215859; called by muse, mutect2, varscan2
- BMPR2 | c.223G>T p.G75W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101001491; called by muse, mutect2
- BNC2 | c.928C>T p.H310Y | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101033214; called by muse, mutect2, varscan2
- BNIPL | c.745C>A p.L249I | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV99764654; called by muse, mutect2, varscan2
- BOD1L1 | c.3878G>A p.R1293K | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99239334; called by muse, mutect2, varscan2
- BOD1L1 | c.728C>T p.T243I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV99239337; called by muse, mutect2, varscan2
- BPIFA3 | c.583A>G p.N195D | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.637); catalogued as COSV100967055; called by muse, mutect2, varscan2
- BPIFB4 | c.619G>T p.G207C | Missense Mutation (SNP) | VAF 64/124 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1363552255, COSV100971521; called by muse, mutect2, varscan2
- BPIFB4 | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100971522; called by muse, mutect2, varscan2
- BPTF | c.2060C>A p.P687H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV100074929; called by muse, mutect2
- BRCA2 | c.6771del p.E2258Kfs*22 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as COSV66460752; called by mutect2, pindel, varscan2
- BRCA2 | c.9819C>A p.F3273L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as COSV101200891; called by muse, mutect2, varscan2
- BRD1 | c.1474dup p.L492Pfs*21 | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | catalogued as rs1232261297; called by mutect2, pindel, varscan2
- BRD2 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100875690; called by muse, mutect2, varscan2
- BRDT | c.150G>A p.W50* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100740322; called by muse, mutect2, varscan2
- BRDT | c.773A>G p.Q258R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV100746363; called by muse, mutect2, varscan2
- BRICD5 | c.155T>A p.L52H | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100063528; called by muse, mutect2, varscan2
- BRINP1 | c.1396G>A p.V466M | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs758271912, COSV56306208; called by muse, mutect2, varscan2
- BRINP3 | c.1760C>A p.P587H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV100818742; called by muse, mutect2, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs1455506786, COSV59000653; called by mutect2, varscan2
- BRWD1 | c.4024G>A p.V1342I | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100313413; called by muse, mutect2, varscan2
- BRWD3 | c.2854G>A p.G952R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100956039; called by muse, mutect2, varscan2
- BRWD3 | c.1379C>T p.T460I | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as COSV100956040; called by muse, mutect2, varscan2
- BRWD3 | c.1265C>T p.T422I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV100956041; called by muse, mutect2, varscan2
- BRWD3 | c.782A>G p.Q261R | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as COSV100956043; called by muse, mutect2, varscan2
- BSN | c.9644C>A p.P3215H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV56527123, COSV99608412; called by muse, mutect2, varscan2
- BTAF1 | c.5076-1G>T p.X1692_splice | Splice Site (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99795319; called by muse, mutect2, varscan2
- BTBD11 | c.1490G>T p.R497M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV55015804, COSV99775697; called by muse, mutect2, varscan2
- BTBD11 | c.2576A>G p.E859G (on ENST00000280758 / NM_001018072.2; = p.E396G on NM_001017523.2) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as COSV99775701; called by muse, mutect2, varscan2
- BTBD2 | c.1189G>T p.V397F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99724734; called by muse, mutect2, varscan2
- BTBD3 | c.833T>C p.L278P | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99655867; called by muse, mutect2, varscan2
- BTBD7 | c.173dup p.R59Efs*14 | Frame Shift Ins (INS) | VAF 7/16 reads (44%) | catalogued as rs752512017; called by mutect2, varscan2
- BTD | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs979837224, COSV57729820; called by muse, mutect2, varscan2
- BTG4 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100604502; called by muse, mutect2, varscan2
- BTLA | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV100569715; called by muse, mutect2, varscan2
- BTN3A2 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1456325093, COSV62687397; called by muse, mutect2, varscan2
- BTN3A2 | c.484A>G p.I162V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); catalogued as COSV100709647; called by muse, mutect2, varscan2
- BUB1 | c.563A>T p.N188I | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV100241247; called by muse, mutect2, varscan2
- BUB3 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV100922187; called by muse, mutect2, varscan2
- BZW1 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100729851; called by muse, mutect2, varscan2
- C10orf71 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100110138; called by muse, mutect2, varscan2
- C11orf45 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100171528; called by muse, mutect2, varscan2
- C11orf71 | c.202G>T p.V68L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); catalogued as COSV100348342; called by muse, mutect2, varscan2
- C12orf66 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs1313475263, COSV100320736; called by muse, mutect2, varscan2
- C14orf119 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV99399590; called by muse, mutect2, varscan2
- C14orf39 | c.1069C>A p.P357T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as COSV100407604; called by muse, mutect2, varscan2
- C15orf39 | c.2872G>A p.A958T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.099); catalogued as COSV100641343; called by mutect2, varscan2
- C16orf46 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.072); catalogued as COSV100215308; called by muse, mutect2, varscan2
- C16orf86 | c.796C>A p.L266I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV99708200; called by muse, mutect2, varscan2
- C16orf89 | c.468G>T p.E156D | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV100280829; called by mutect2, varscan2
- C17orf80 | c.52T>A p.F18I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99278076; called by muse, mutect2, varscan2
- C18orf54 | c.590-1G>A p.X197_splice | Splice Site (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100266505; called by muse, mutect2, varscan2
- C19orf47 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs757690643, COSV100775080; called by muse, mutect2, varscan2
- C19orf73 | c.12G>T p.K4N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV99674465; called by muse, mutect2, varscan2
- C1D | c.305A>T p.D102V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV100878209; called by muse, mutect2, varscan2
- C1QL2 | c.743G>A p.S248N | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99733185; called by muse, mutect2, varscan2
- C1QTNF2 | c.569G>A p.S190N (on ENST00000393975; = p.S145N on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV101220860; called by muse, mutect2, varscan2
- C1QTNF2 | c.370G>T p.G124* (on ENST00000393975; = p.G79* on NM_031908.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV101220861; called by muse, mutect2, varscan2
- C1QTNF9B | c.431C>A p.P144H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV101158573; called by muse, mutect2, varscan2
- C1orf112 | c.2144C>T p.A715V | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as rs748148197, COSV53681175; called by muse, mutect2, varscan2
- C1orf226 | c.437G>T p.S146I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100908072; called by muse, mutect2, varscan2
- C1orf53 | c.273G>T p.Q91H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100956450; called by muse, mutect2, varscan2
- C1orf87 | c.599A>G p.K200R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.548); catalogued as COSV100967062; called by muse, mutect2, varscan2
- C22orf31 | c.3+1G>A p.X1_splice | Splice Site (SNP) | VAF 4/17 reads (24%) | catalogued as COSV99326366; called by muse, mutect2, varscan2
- C2CD3 | c.2938G>T p.A980S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.325); catalogued as COSV100486673; called by muse, mutect2, varscan2
- C2CD3 | c.305A>G p.Q102R | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100076427; called by muse, mutect2, varscan2
- C2orf16 | c.5483G>T p.R1828M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.758); catalogued as COSV100820797; called by muse, mutect2, varscan2
- C2orf73 | c.127C>T p.H43Y | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100471325; called by muse, mutect2, varscan2
- C3 | c.1604A>G p.Y535C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1412617510, COSV55570466; called by muse, mutect2, varscan2
- C3 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55573509, COSV99836634; called by muse, mutect2, varscan2
- C3 | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.093); catalogued as COSV99836636; called by muse, mutect2, varscan2
- C3orf20 | c.1615C>T p.R539* | Nonsense Mutation (SNP) | VAF 15/29 reads (52%) | catalogued as rs376607245; called by muse, mutect2, varscan2
- C3orf56 | c.102G>A p.W34* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV101228957; called by muse, mutect2, varscan2
- C3orf56 | c.538T>A p.L180M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as COSV101228958; called by muse, mutect2, varscan2
- C4BPB | c.260T>C p.V87A | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV99700003; called by muse, mutect2, varscan2
- C5 | c.5023G>T p.G1675* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99797842; called by muse, mutect2, varscan2
- C5 | c.4734G>T p.K1578N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV56326472, COSV99797847; called by muse, mutect2, varscan2
- C5orf51 | c.100+1G>A p.X34_splice | Splice Site (SNP) | VAF 22/63 reads (35%) | catalogued as COSV101068962; called by muse, mutect2, varscan2
- C6 | c.69C>A p.F23L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.637); catalogued as COSV54705890, COSV99667070; called by muse, mutect2, varscan2
- C6orf118 | c.1070G>T p.S357I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100024507; called by muse, mutect2, varscan2
- C6orf118 | c.743A>G p.K248R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV100024510; called by muse, mutect2, varscan2
- C6orf15 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as COSV99456855; called by muse, mutect2, varscan2
- C9orf24 | c.289T>C p.C97R | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.667); catalogued as COSV99897916; called by muse, mutect2, varscan2
- CA1 | c.556C>A p.L186I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV56279080, COSV99810056; called by muse, mutect2, varscan2
- CABLES1 | c.1028G>A p.G343D (on ENST00000256925 / NM_001100619.2; = p.G78D on NM_138375.2) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1464598564, COSV99908629; called by muse, mutect2, varscan2
- CABLES1 | c.1709C>T p.A570V (on ENST00000256925 / NM_001100619.2; = p.A305V on NM_138375.2) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99908631; called by muse, mutect2, varscan2
- CACHD1 | c.2582C>A p.P861H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1175269039, COSV99262251; called by muse, mutect2, varscan2
- CACHD1 | c.3129G>T p.M1043I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV99262256; called by muse, mutect2, varscan2
- CACHD1 | c.3298G>A p.A1100T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV99262261; called by muse, varscan2
- CACNA1C | c.3019A>G p.R1007G | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100218776; called by muse, mutect2, varscan2
- CACNA1C | c.5841G>T p.K1947N (on ENST00000399634 / NM_001167625.1; = p.K1876N on NM_000719.7) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.021); catalogued as COSV100218783; called by muse, mutect2, varscan2
- CACNA1D | c.1040T>C p.F347S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99858147; called by muse, mutect2, varscan2
- CACNA1E | c.1354G>A p.V452I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV100702588; called by muse, mutect2, varscan2
- CACNA1F | c.5635C>T p.H1879Y | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.026); catalogued as COSV100544803; called by muse, mutect2, varscan2
- CACNA1F | c.5126G>T p.S1709I | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as COSV100544806; called by muse, mutect2, varscan2
- CACNA1F | c.3569C>T p.A1190V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV100544807; called by muse, varscan2
- CACNA1G | c.6199A>G p.R2067G | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100661790; called by muse, mutect2, varscan2
- CACNA1I | c.4666C>A p.L1556M | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV60807090; called by muse, mutect2, varscan2
- CACNA1I | c.5003T>C p.F1668S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100360254; called by muse, mutect2, varscan2
- CACNA2D4 | c.2320G>A p.G774S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.382); catalogued as COSV99765650, COSV99766365; called by muse, mutect2, varscan2
- CACNB2 | c.1117C>A p.L373I (on ENST00000324631 / NM_201596.3; = p.L318I on NM_000724.4) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as COSV99994533; called by muse, mutect2, varscan2
- CACNB4 | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.185); catalogued as COSV99138234; called by muse, mutect2, varscan2
- CADPS | c.3821C>T p.T1274M | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs754461043, COSV99338178; called by muse, mutect2, varscan2
- CAGE1 | c.1464G>T p.Q488H (on ENST00000512086; = p.Q352H on NM_205864.3) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV99699682; called by muse, mutect2, varscan2
- CALCR | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV100810533; called by muse, mutect2, varscan2
- CALM1 | c.422-1G>T p.X141_splice | Splice Site (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100811151; called by muse, mutect2, varscan2
- CAMK2A | c.890G>T p.R297M | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as COSV100652023; called by muse, mutect2
- CAMKK1 | c.1333A>G p.T445A | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV99340269, COSV99340575; called by muse, varscan2
- CAMKK1 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs191868145, COSV99340270; called by muse, varscan2
- CAMSAP1 | c.2150T>C p.V717A | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100409840; called by muse, mutect2, varscan2
- CAMSAP2 | c.1340A>G p.E447G (on ENST00000236925 / NM_001297707.2; = p.E436G on NM_203459.3) | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.889); catalogued as COSV99373371; called by mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAMSAP3 | c.1962G>T p.E654D | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV99350681; called by muse, varscan2
- CAMSAP3 | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.154); catalogued as COSV50331088; called by muse, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs745547658; called by mutect2, varscan2
- CAMTA2 | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV100772604; called by muse, mutect2, varscan2
- CAPG | c.670C>A p.L224M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV99809370; called by muse, mutect2, varscan2
- CAPG | c.196+2T>C p.X66_splice | Splice Site (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99809411; called by muse, mutect2, varscan2
- CAPN13 | c.956A>G p.D319G | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99700228; called by muse, mutect2
- CAPN3 | c.2055G>T p.K685N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99782573; called by muse, mutect2, varscan2
- CAPN6 | c.1673C>T p.T558I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV100136870; called by muse, mutect2, varscan2
- CAPN7 | c.202C>T p.H68Y | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs1485153208, COSV99512772; called by mutect2, varscan2
- CAPN7 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV99512774; called by muse, mutect2, varscan2
- CAPN7 | c.1405A>G p.K469E | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV99512777; called by muse, mutect2, varscan2
- CAPN9 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | catalogued as COSV55238401; called by muse, mutect2, varscan2
- CAPRIN2 | c.1738A>T p.N580Y | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV99195499; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CARD6 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV99620795; called by muse, mutect2, varscan2
- CARMIL1 | c.3073G>T p.G1025C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100277782; called by muse, mutect2, varscan2
- CARMIL3 | c.4015del p.L1339* | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs1167529280; called by pindel, varscan2
- CASP1 | c.614dup p.N205Kfs*24 (on ENST00000436863 / NM_033292.4; = p.N184Kfs*24 on NM_001223.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | catalogued as rs746543598; called by mutect2, varscan2
- CASP1 | c.33G>T p.K11N | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.756); catalogued as rs772341424, COSV100782778; called by muse, mutect2, varscan2
- CASP10 | c.816G>A p.R272= (on ENST00000272879 / NM_032974.5; = p.R229= on NM_001230.5) | Splice Region (SNP) | VAF 17/27 reads (63%) | catalogued as rs113867411, COSV53780745; called by muse, varscan2
- CASP8 | c.79C>A p.L27M | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.213); catalogued as COSV99965187; called by muse, mutect2, varscan2
- CASP8 | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV99965188; called by muse, mutect2, varscan2
- CASP8AP2 | c.613C>T p.H205Y | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.801); catalogued as COSV99387053; called by muse, mutect2, varscan2
- CASP8AP2 | c.5396C>T p.T1799I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs780392411, COSV99387054; called by mutect2, varscan2
- CASQ1 | c.790C>A p.L264M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.852); catalogued as COSV100927291; called by muse, mutect2, varscan2
- CASR | c.2426G>A p.R809Q (on ENST00000490131; = p.R886Q on NM_000388.4) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.482); catalogued as rs1057520791, CM021965, COSV56137639; called by muse, mutect2, varscan2
- CASS4 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.386); catalogued as COSV100824682; called by muse, mutect2, varscan2
- CASS4 | c.1782G>T p.K594N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV100824685; called by muse, mutect2
- CAST | c.762G>A p.E254= (on ENST00000341926; = p.E337= on NM_001750.7 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 11/26 reads (42%) | catalogued as rs774410415, COSV100352393; called by muse, mutect2, varscan2
- CAT | c.727A>G p.K243E | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.24); catalogued as COSV99573230; called by muse, mutect2, varscan2
- CBFA2T3 | c.28del p.A10Qfs*60 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | catalogued as COSV51933816; called by mutect2, pindel, varscan2
- CBL | c.2149T>C p.S717P | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.121); catalogued as COSV99876260; called by muse, mutect2, varscan2
- CBR3 | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as COSV99289807; called by muse, mutect2, varscan2
- CBWD2 | c.71C>A p.P24H | Missense Mutation (SNP) | VAF 113/286 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99380525; called by muse, mutect2, varscan2
- CC2D1B | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780762958, COSV99429972; called by muse, mutect2, varscan2
- CCDC102B | c.223C>A p.L75M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV100103486; called by muse, mutect2, varscan2
- CCDC112 | c.1321G>T p.G441* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV101100450; called by muse, mutect2, varscan2
- CCDC112 | c.194C>T p.T65I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101100451; called by muse, mutect2, varscan2
- CCDC125 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV101143595; called by muse, mutect2, varscan2
- CCDC136 | c.1641G>T p.Q547H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.363); catalogued as COSV99922619; called by muse, mutect2, varscan2
- CCDC136 | c.3148G>A p.V1050M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99922622; called by muse, mutect2, varscan2
- CCDC144A | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV100138531; called by muse, varscan2
- CCDC149 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751805391, COSV60880955, COSV60880969; called by muse, mutect2, varscan2
- CCDC150 | c.429G>T p.Q143H | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.977); catalogued as COSV99776905; called by muse, mutect2, varscan2
- CCDC150 | c.2903C>T p.A968V | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.058); catalogued as COSV99776906; called by muse, mutect2
- CCDC158 | c.2365G>A p.A789T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV101187242; called by muse, mutect2, varscan2
- CCDC159 | c.257A>G p.E86G | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99264467; called by muse, mutect2, varscan2
- CCDC159 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs1286616016, COSV99264468; called by muse, mutect2, varscan2
- CCDC160 | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV100892114; called by muse, mutect2, varscan2
- CCDC171 | c.745T>C p.S249P | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99900657; called by muse, mutect2
- CCDC172 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV100319782; called by muse, mutect2, varscan2
- CCDC174 | c.42+2T>C p.X14_splice | Splice Site (SNP) | VAF 11/53 reads (21%) | catalogued as COSV100358579; called by muse, mutect2, varscan2
- CCDC174 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57980264; called by muse, mutect2, varscan2
- CCDC181 | c.1191G>T p.K397N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100890260; called by muse, mutect2, varscan2
- CCDC186 | c.1666G>T p.E556* | Nonsense Mutation (SNP) | VAF 5/9 reads (56%) | catalogued as COSV100991112; called by muse, mutect2, varscan2
- CCDC189 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs768683366, COSV100079582; ClinVar: uncertain significance; called by mutect2, varscan2
- CCDC191 | c.2249G>T p.R750M | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV99878251; called by muse, mutect2, varscan2
- CCDC191 | c.1336A>G p.S446G | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV99878252; called by muse, mutect2, varscan2
- CCDC33 | c.598G>T p.V200L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as COSV100351386; called by muse, mutect2, varscan2
- CCDC42 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs182957223, COSV99549788; called by muse, mutect2, varscan2
- CCDC43 | c.230G>A p.C77Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV100188984; called by muse, mutect2, varscan2
- CCDC54 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs753526671, COSV53758564, COSV99660345; called by muse, mutect2, varscan2
- CCDC59 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99810666; called by muse, mutect2, varscan2
- CCDC60 | c.342C>T p.S114= | Splice Region (SNP) | VAF 12/30 reads (40%) | catalogued as rs1235658064, COSV100555080; called by muse, varscan2
- CCDC60 | c.356A>T p.E119V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV100555083; called by muse, varscan2
- CCDC69 | c.284G>T p.R95M | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV100815163; called by muse, mutect2, varscan2
- CCDC73 | c.2972G>T p.S991I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100067417; called by muse, mutect2, varscan2
- CCDC74B | c.368T>C p.V123A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs750059678, COSV100134454; called by mutect2, varscan2
- CCDC74B | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100134459; called by muse, mutect2, varscan2
- CCDC8 | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.373); catalogued as COSV100281930; called by muse, mutect2, varscan2
- CCDC82 | c.1265G>A p.C422Y | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.652); catalogued as rs145938297; called by muse, mutect2, varscan2
- CCDC88C | c.1202G>T p.R401L | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66235431, COSV66238985; called by muse, mutect2, varscan2
- CCDC93 | c.1728G>T p.K576N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60121412; called by muse, varscan2
- CCDC9B | c.609dup p.T204Hfs*56 | Frame Shift Ins (INS) | VAF 28/58 reads (48%) | catalogued as rs772754432; called by mutect2, varscan2
- CCHCR1 | c.1053G>T p.Q351H | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100885634; called by muse, mutect2, varscan2
- CCIN | c.510G>T p.M170I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100631822, COSV58724517; called by muse, mutect2, varscan2
- CCN4 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs536884015, COSV51530693; called by muse, mutect2, varscan2
- CCN5 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs773560216, COSV51939628; called by muse, mutect2, varscan2
- CCND2 | c.196-1G>T p.X66_splice | Splice Site (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99714226; called by muse, mutect2, varscan2
- CCND2 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as rs1345554353, COSV99713914, COSV99714229; called by muse, mutect2, varscan2
- CCNDBP1 | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99543940; called by muse, mutect2
- CCNE1 | c.560T>C p.L187P | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.932); catalogued as COSV99388388; called by muse, varscan2
- CCNE2 | c.199A>G p.S67G | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as COSV100353758; called by muse, mutect2, varscan2
- CCNI | c.815G>A p.C272Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99423427; called by muse, mutect2, varscan2
- CCNI | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.737); catalogued as COSV99423432; called by muse, mutect2, varscan2
- CCNJ | c.1066A>G p.S356G | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV99796236; called by muse, mutect2, varscan2
- CCNP | c.7G>A p.V3M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99695865; called by muse, mutect2, varscan2
- CCSER1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100391504; called by muse, mutect2, varscan2
- CCSER1 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.106); catalogued as COSV100391509; called by muse, mutect2, varscan2
- CCSER1 | c.1853C>A p.S618Y | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100392781, COSV61409430, COSV61424125; called by muse, mutect2, varscan2
- CCT7 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.057); catalogued as rs758161315, COSV99240797; called by muse, mutect2, varscan2
- CD109 | c.821G>A p.W274* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV99753590; called by muse, mutect2, varscan2
- CD109 | c.953C>A p.P318H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV99753593; called by muse, mutect2, varscan2
- CD163L1 | c.386A>G p.H129R | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.333); catalogued as COSV100550063; called by muse, mutect2, varscan2
- CD248 | c.2020G>T p.A674S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100256583; called by muse, mutect2, varscan2
- CD276 | c.1169C>A p.P390H (on ENST00000318443 / NM_001024736.2; = p.P172H on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100573364; called by muse, varscan2
- CD2AP | c.694T>C p.S232P | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100830422; called by muse, mutect2, varscan2
- CD2BP2 | c.218-1G>A p.X73_splice | Splice Site (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99977082; called by muse, mutect2, varscan2
- CD320 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.376); catalogued as COSV100035796; called by muse, mutect2, varscan2
- CD3E | c.518G>T p.R173M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100688938, COSV100688981; called by muse, mutect2, varscan2
- CD4 | c.214G>T p.G72C | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99163765; called by muse, mutect2, varscan2
- CD4 | c.916G>T p.G306* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV99163768; called by muse, mutect2, varscan2
- CD40 | c.583C>A p.L195M | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV100953838, COSV64847858; called by muse, mutect2, varscan2
- CD52 | c.16T>C p.F6L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV100366675; called by muse, mutect2, varscan2
- CD72 | c.1064T>C p.F355S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV99427433; called by muse, mutect2, varscan2
- CD72 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.186); catalogued as COSV99427439; called by muse, mutect2, varscan2
- CD80 | c.316C>A p.L106M | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99958254; called by muse, mutect2, varscan2
- CD81 | c.512A>T p.K171M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99719197; called by muse, mutect2, varscan2
- CDAN1 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV99141540; called by muse, mutect2, varscan2
- CDC42BPB | c.4548C>A p.N1516K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV100775434; called by mutect2, varscan2
- CDC42BPG | c.4364G>A p.R1455Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV61348793; called by muse, mutect2, varscan2
- CDC5L | c.2212T>G p.L738V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV101015034; called by muse, mutect2, varscan2
- CDC7 | c.79T>C p.S27P | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99319725; called by muse, mutect2, varscan2
- CDCA3 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.204); catalogued as COSV99976925; called by muse, mutect2, varscan2
- CDCP2 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100313473; called by muse, mutect2, varscan2
- CDH10 | c.1034C>T p.T345I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.29); catalogued as rs182867464, COSV100051394; called by muse, mutect2, varscan2
- CDH11 | c.2093C>A p.P698H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV51760859; called by muse, mutect2, varscan2
- CDH13 | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99225943; called by muse, mutect2, varscan2
- CDH16 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs199875828, COSV100233875; called by muse, mutect2, varscan2
- CDH17 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as rs772838670, COSV99217428; called by muse, mutect2, varscan2
- CDH20 | c.2236C>T p.Q746* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as COSV53010838, COSV99406756; called by muse, mutect2, varscan2
- CDH3 | c.461dup p.E155* | Frame Shift Ins (INS) | VAF 17/36 reads (47%) | catalogued as rs1437616632; called by mutect2, pindel, varscan2
- CDH3 | c.866A>G p.E289G | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99868315; called by muse, mutect2, varscan2
- CDH4 | c.2116A>G p.I706V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.338); catalogued as COSV100848805; called by muse, varscan2
- CDH7 | c.1909C>T p.P637S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.433); catalogued as COSV100542349, COSV59889899; called by muse, mutect2, varscan2
- CDH8 | c.1834G>T p.A612S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100181490; called by muse, mutect2, varscan2
- CDH8 | c.612G>T p.K204N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100181491; called by muse, mutect2, varscan2
- CDHR2 | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.334); catalogued as COSV99991583; called by muse, mutect2, varscan2
- CDHR2 | c.1195-1G>T p.X399_splice | Splice Site (SNP) | VAF 10/48 reads (21%) | catalogued as COSV56144332; called by muse, mutect2, varscan2
- CDHR3 | c.1336T>C p.Y446H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV100488337; called by muse, mutect2, varscan2
- CDHR3 | c.2398A>G p.K800E | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV100488345; called by muse, mutect2, varscan2
- CDK10 | c.111G>T p.K37N | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100450795; called by muse, mutect2, varscan2
- CDK10 | c.545T>C p.F182S (on ENST00000353379 / NM_052988.5; = p.F111S on NM_052987.4) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99232290; called by muse, mutect2, varscan2
- CDK12 | c.2743C>T p.P915S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71001040; called by muse, mutect2, varscan2
- CDK13 | c.2735C>A p.P912H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99475514; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4052C>A p.P1351H | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100575441, COSV62573706; called by muse, mutect2, varscan2
- CDK8 | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101037244; called by muse, mutect2, varscan2
- CDKL3 | c.1720G>A p.G574S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as rs760568903, COSV54740619; called by muse, mutect2, varscan2
- CDKL4 | c.935C>A p.P312H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV101115279; called by muse, mutect2, varscan2
- CDKL5 | c.2924G>A p.C975Y | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV101183801; called by muse, mutect2, varscan2
- CDKN1B | c.374_375del p.S125* | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as rs786201011; called by pindel, varscan2
- CDKN2AIP | c.1446dup p.V483Cfs*13 | Frame Shift Ins (INS) | VAF 5/17 reads (29%) | catalogued as rs1303422391; called by mutect2, pindel, varscan2
- CDRT4 | c.236G>T p.R79M | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100381553; called by muse, mutect2, varscan2
- CDS1 | c.810G>A p.K270= | Splice Region (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99880705; called by muse, mutect2, varscan2
- CDYL2 | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs1243992802, COSV101629560; called by muse, mutect2, varscan2
- CEACAM3 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.169); catalogued as COSV99704963; called by muse, mutect2
- CEACAM7 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV50073440; called by muse, mutect2, varscan2
- CEBPE | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52829949; called by muse, mutect2, varscan2
- CEBPZ | c.1428del p.D477Mfs*11 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs763090473; called by mutect2, varscan2
- CECR2 | c.1075C>T p.R359C (on ENST00000342247 / NM_001290047.2; = p.R196C on NM_001290046.1) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770569105, COSV52846673; called by muse, mutect2, varscan2
- CELF3 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs202171109, COSV99310292; called by muse, mutect2, varscan2
- CELF4 | c.443del p.P148Lfs*50 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | catalogued as COSV58468517; called by mutect2, pindel, varscan2
- CELSR1 | c.5828C>T p.P1943L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs564623506, COSV53086846; called by muse, mutect2, varscan2
- CELSR1 | c.5263G>A p.G1755S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as rs745985122, COSV53087180, COSV53098535; called by muse, mutect2, varscan2
- CELSR1 | c.5172G>T p.E1724D | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.348); catalogued as COSV99418259; called by muse, mutect2, varscan2
- CELSR2 | c.1431G>T p.Q477H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs748146968, COSV99603805; called by muse, mutect2, varscan2
- CELSR2 | c.8342G>A p.G2781E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.001); catalogued as COSV99603806; called by muse, mutect2, varscan2
- CELSR3 | c.6642G>T p.E2214D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV99373505; called by muse, mutect2, varscan2
- CENPB | c.1679C>T p.S560F | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100713433; called by muse, mutect2, varscan2
- CENPC | c.1625G>A p.S542N | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV99893916; called by muse, mutect2
- CENPF | c.8486G>A p.G2829D | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV100871684; called by muse, mutect2, varscan2
- CENPJ | c.2765C>T p.A922V | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV101121509, COSV67883410; called by muse, varscan2
- CENPN | c.271G>T p.G91* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100001311; called by muse, mutect2, varscan2
- CENPQ | c.760A>G p.M254V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV100225759; called by muse, mutect2, varscan2
- CENPT | c.535A>G p.N179D | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.311); catalogued as COSV99535075; called by muse, mutect2, varscan2
- CEP120 | c.977T>C p.V326A | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs1365764641, COSV100071095; called by muse, mutect2, varscan2
- CEP170 | c.3877C>T p.R1293* | Nonsense Mutation (SNP) | VAF 21/45 reads (47%) | catalogued as COSV100317061; called by muse, mutect2, varscan2
- CEP170B | c.2363G>T p.R788M (on ENST00000453495; = p.R717M on NM_015005.3) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV101371502; called by muse, mutect2, varscan2
- CEP250 | c.1539G>T p.E513D | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.601); catalogued as COSV100698924; called by muse, mutect2
- CEP350 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as rs1246115083, COSV100658299; called by muse, mutect2, varscan2
- CEP350 | c.6043G>A p.G2015R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs1366885206, COSV100854670; called by muse, mutect2, varscan2
- CEP89 | c.37T>G p.F13V | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV99578876; called by muse, mutect2, varscan2
- CER1 | c.710A>T p.E237V | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV101097818, COSV66602913; called by muse, mutect2, varscan2
- CERS6 | c.150G>A p.M50I | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99987038; called by muse, mutect2, varscan2
- CERS6 | c.829G>T p.G277C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV99987041; called by muse, mutect2, varscan2
6,469 further variants in this file (4,451 protein-altering or splice-affecting, 1,836 silent, 182 other) are not listed here.
